Somatic mutation profile of tumor specimen TCGA-WY-A85E-01A (aliquot TCGA-WY-A85E-01A-11D-A36O-08) from TCGA case TCGA-WY-A85E, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 48.9 years (17,878 days).
Specimen TCGA-WY-A85E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f4b5873-165b-4783-b6c4-40b981fc68d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WY-A85E-10A (Blood Derived Normal), aliquot TCGA-WY-A85E-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47d468f8-3cbb-4f71-996d-09e9cd08c4f2

The open-access MAF lists 58 somatic variants for this specimen: 43 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 36, Silent 15, Nonsense Mutation 5, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 26/82 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 5/73 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1057519872, COSV55911123; ClinVar: not provided; called by muse, mutect2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 29/32 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.6940A>C p.N2314H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.659); catalogued as COSV100717091; called by muse, mutect2, varscan2
- ACSBG1 | c.1031G>A p.W344* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as rs942945597, COSV51908283, COSV99357024; called by muse, mutect2, varscan2
- APOB | c.8825A>G p.H2942R | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99263717; called by muse, mutect2
- ATRX | c.2451T>A p.Y817* | Nonsense Mutation (SNP) | VAF 76/186 reads (41%) | catalogued as COSV100970096; called by muse, mutect2, varscan2
- BCKDHB | c.1129C>G p.P377A | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100243269; called by muse, mutect2, varscan2
- C9orf116 | c.13T>C p.C5R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54093116, COSV99613266; called by muse, mutect2, varscan2
- CLCN7 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1400598641, COSV99246906; called by muse, mutect2, varscan2
- CXXC1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs755803985, COSV99495481; called by muse, mutect2, varscan2
- DPYD | c.2844T>G p.I948M | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100928654; called by muse, mutect2
- DYDC2 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192021279, COSV99757987; called by muse, mutect2, varscan2
- ESRP1 | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV100619162, COSV64410523; called by muse, mutect2, varscan2
- GABBR2 | c.2660+1G>T p.X887_splice | Splice Site (SNP) | VAF 38/175 reads (22%) | catalogued as COSV99409248; called by muse, mutect2, varscan2
- GPRC6A | c.415A>G p.R139G | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as COSV100114026; called by muse, mutect2
- HPSE2 | c.992T>A p.V331D | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100985022, COSV65203673; called by muse, mutect2, varscan2
- IL10 | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV100894722, COSV65594968; called by muse, mutect2, varscan2
- IL6R | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs373575595; called by muse, mutect2
- IQSEC2 | c.2420T>C p.L807P (on ENST00000642864 / NM_001111125.3; = p.L602P on NM_015075.2) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100944743; called by muse, mutect2, varscan2
- ITIH6 | c.2686C>G p.P896A | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.039); catalogued as COSV99512858; called by muse, mutect2, varscan2
- KIAA1210 | c.2038C>A p.Q680K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.55); catalogued as rs771652518, COSV101273925; called by muse, mutect2, varscan2
- LRRN1 | c.779A>G p.Q260R | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100076048; called by muse, mutect2, varscan2
- MDFIC | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99994886; called by muse, mutect2, varscan2
- MORC1 | c.929T>G p.V310G | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as COSV99225148; called by muse, mutect2, varscan2
- MORC4 | c.2573A>T p.E858V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99716817; called by muse, mutect2, varscan2
- MUC16 | c.20584A>C p.S6862R | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as rs1022749803, COSV101198209; called by muse, mutect2, varscan2
- MYT1L | c.1805T>C p.V602A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as rs1253746973, COSV101218907; called by muse, mutect2
- NEFM | c.1773G>T p.K591N | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV99646963; called by muse, mutect2
- NPSR1 | c.932C>A p.A311D | Missense Mutation (SNP) | VAF 15/241 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100705761; called by muse, mutect2
- OR51M1 | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100150130; called by muse, mutect2, varscan2
- OR6S1 | c.623T>C p.L208P | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.934); catalogued as COSV100289277; called by muse, mutect2
- PIK3CD | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs756497515, COSV63128332; called by muse, mutect2, varscan2
- PRDM2 | c.1271T>G p.L424R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); catalogued as COSV99340890; called by muse, mutect2, varscan2
- SIGLEC5 | c.1460C>T p.T487I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs768255375, COSV99707126; called by muse, mutect2, varscan2
- SLC6A15 | c.1713T>A p.Y571* | Nonsense Mutation (SNP) | VAF 54/139 reads (39%) | catalogued as COSV99880195; called by muse, mutect2, varscan2
- TACC1 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99392955; called by muse, mutect2, varscan2
- THSD7B | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.615); catalogued as COSV99744738; called by muse, mutect2
- TMEM134 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs754993164, COSV100339415; called by muse, mutect2, varscan2
- YPEL2 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 19/112 reads (17%) | catalogued as COSV100445159; called by muse, mutect2, varscan2
- ZNF816 | c.776G>A p.C259Y | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs776113868, COSV54412543; called by muse, mutect2, varscan2
- FLNC | c.6315del p.G2106Afs*21 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- OR11H1 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.055); called by mutect2, varscan2
- ACVR2B | c.330C>T p.N110= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs528729033, COSV100754159; called by muse, mutect2
- AXDND1 | c.2490T>A p.L830= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100858248; called by muse, mutect2, varscan2
- BTNL3 | c.900G>A p.K300= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs559284545, COSV100732178; called by muse, mutect2, varscan2
- CORIN | c.2580C>T p.I860= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV99902928; called by muse, mutect2, varscan2
- CPED1 | c.870G>T p.S290= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs774206526, COSV60014767; called by muse, mutect2, varscan2
- CSN3 | c.507C>A p.T169= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100515258, COSV100515307; called by muse, mutect2
- DCAF12L2 | c.135G>A p.P45= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV63584397; called by mutect2, varscan2
- HSF5 | c.150G>T p.L50= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs773682122, COSV100050779; called by muse, varscan2
- ITGA2 | c.1242T>C p.H414= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV99670254; called by muse, mutect2, varscan2
- OBSCN | c.10245C>T p.C3415= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs573798549, COSV52749833; called by muse, mutect2, varscan2
- PITPNM1 | c.1257G>A p.L419= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- PITX2 | c.768G>T p.A256= (on ENST00000354925 / NM_001204397.1; = p.A263= on NM_000325.6) | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100146206; called by muse, mutect2, varscan2
- SPATS2L | c.582A>T p.T194= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV100660487; called by muse, mutect2, varscan2
- TRPA1 | c.1032T>C p.S344= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs766298427, COSV100083214; called by muse, mutect2, varscan2
- WNT3 | c.210C>G p.A70= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV56644024, COSV99843066; called by muse, mutect2, varscan2
